Somatic mutation profile of tumor specimen MMRF_2083_1_BM_CD138pos (aliquot MMRF_2083_1_BM_CD138pos_T1_KHS5U_L08639) from MMRF case MMRF_2083, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,404 days).
Specimen MMRF_2083_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9919a3c6-920b-415a-bd18-8e70acae4540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2083_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2083_1_PB_Whole_C2_KHS5U_L08640; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40a49010-e0ac-4701-8edb-34da2cbe371d

The open-access MAF lists 98 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 26, Silent 11, Intron 7, 5'Flank 6, 5'UTR 5, 3'Flank 4, RNA 4, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 46/84 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 40/96 reads (42%) | catalogued as rs767549806; called by mutect2, varscan2
- ANO4 | c.1713A>T p.K571N (on ENST00000392977 / NM_001286615.2; = p.K536N on NM_178826.4) | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54609704; called by muse, mutect2, varscan2
- ARHGEF28 | c.4397C>T p.A1466V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1269218553; called by muse, mutect2, varscan2
- CCND1 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57122832; called by muse, mutect2, varscan2
- CFAP221 | c.1203del p.A402Hfs*7 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | catalogued as COSV54656906; called by mutect2, pindel, varscan2
- DACT2 | c.1746C>A p.S582R | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV64694296; called by muse, mutect2, varscan2
- E2F7 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as rs201812783, COSV59737248; called by muse, mutect2, varscan2
- FREM3 | c.3949G>C p.V1317L | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV61682094; called by muse, mutect2, varscan2
- H2BC11 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60361711; called by muse, mutect2, varscan2
- IGLV3-1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs754927085; called by muse, varscan2
- IGLV3-1 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs529856363; called by muse, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, varscan2
- MPZ | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60667609; called by muse, mutect2, varscan2
- OLFML2A | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs372603527, COSV56585745; called by muse, mutect2
- PNKP | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1187151464; called by muse, mutect2, varscan2
- SPTA1 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs748522821, COSV63748200; called by muse, mutect2, varscan2
- TRIM55 | c.986-1G>C p.X329_splice | Splice Site (SNP) | VAF 17/31 reads (55%) | catalogued as COSV52547214; called by muse, mutect2, varscan2
- WDFY3 | c.6625C>T p.H2209Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV55712843; called by muse, mutect2, varscan2
- ADGRV1 | c.13433+2T>A p.X4478_splice | Splice Site (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- AKAP13 | c.7399A>G p.T2467A (on ENST00000394518 / NM_007200.5; = p.T2471A on NM_006738.6) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP1A2 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- FAM227B | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGHV1-69D | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, varscan2
- KRT7 | c.994T>A p.L332M | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- M6PR | c.824T>C p.L275S | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH9 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- NTSR1 | c.377A>C p.N126T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- OR8G2P | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SALL4 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- SEL1L3 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- SLC19A3 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- TACR2 | c.1128_1129insA p.Q377Tfs*21 | Frame Shift Ins (INS) | VAF 64/177 reads (36%) | called by mutect2, pindel, varscan2
- TRBV5-1 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2
- APOB | c.10677A>C p.I3559= | Silent (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- CHRNA2 | c.48G>T p.L16= | Silent (SNP) | VAF 59/124 reads (48%) | called by muse, mutect2, varscan2
- ELOVL4 | c.54A>G p.A18= | Silent (SNP) | VAF 85/195 reads (44%) | catalogued as rs745792192; called by muse, mutect2, varscan2
- FMN2 | c.2172A>G p.E724= | Silent (SNP) | VAF 67/158 reads (42%) | catalogued as rs1414556146; called by muse, mutect2, varscan2
- HBD | c.274C>T p.L92= | Silent (SNP) | VAF 92/188 reads (49%) | catalogued as rs755850441; called by muse, mutect2, varscan2
- IGSF9 | c.2601C>T p.G867= (on ENST00000368094 / NM_001135050.2; = p.G851= on NM_020789.4) | Silent (SNP) | VAF 54/93 reads (58%) | called by muse, mutect2, varscan2
- PLCH2 | c.3753T>C p.A1251= | Silent (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.1011G>A p.P337= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as rs768772830; called by muse, mutect2, varscan2
- SNX18 | c.210C>T p.G70= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs994492658; called by muse, mutect2
- TRO | c.4008C>A p.G1336= | Silent (SNP) | VAF 87/188 reads (46%) | called by muse, mutect2, varscan2
- ZBTB11 | c.2574G>T p.R858= | Silent (SNP) | VAF 15/224 reads (7%) | catalogued as rs1482714878; called by muse, mutect2
- ATP8A2 | c.*4311T>C | 3'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021153 G>C | 5'Flank (SNP) | VAF 62/148 reads (42%) | catalogued as rs1012416032, COSV55847562, COSV55847818; called by muse, mutect2, varscan2
- BLCAP | c.*1371C>G | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- C5orf49 | c.*644T>C | 3'UTR (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- CACNG8 | c.*989T>G | 3'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- CDH19 | c.-105G>A | 5'UTR (SNP) | VAF 57/110 reads (52%) | called by muse, mutect2, varscan2
- CTSL3P | n.469C>T | RNA (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- DCAF11 | c.*40A>C | 3'UTR (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- DCHS2 | n.2616G>A | RNA (SNP) | VAF 41/81 reads (51%) | catalogued as rs760166424; called by muse, mutect2, varscan2
- DCK | c.*859A>G | 3'UTR (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- DDX27 | c.1367-47A>G | Intron (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- DNAJC19 | chr3:180989790 G>A | 5'Flank (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- DOK6 | c.-85G>A | 5'UTR (SNP) | VAF 12/41 reads (29%) | catalogued as rs574893333; called by muse, mutect2, varscan2
- EEF1A1 | chr6:73521102 C>A | 5'Flank (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- EGLN3 | c.*560A>C | 3'UTR (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- FAM133A | c.*967T>G | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85529647 C>T | 5'Flank (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161898959 A>T | 3'Flank (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2
- GRIK2 | c.-192C>T | 5'UTR (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- HABP2 | c.*213A>C | 3'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.43-30T>C | Intron (SNP) | VAF 15/37 reads (41%) | catalogued as rs1444866150; called by muse, mutect2, varscan2
- HYDIN2 | n.4378G>A | RNA (SNP) | VAF 10/29 reads (34%) | catalogued as rs1187542740; called by muse, mutect2, varscan2
- INHBA | c.*1503A>G | 3'UTR (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- ITGB1BP2 | c.816+98G>A | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- KCTD21 | c.*1342G>A | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- KIF21B | chr1:200970044 C>G | 3'Flank (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- KIF21B | chr1:200970045 T>G | 3'Flank (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- LMNA | c.-169G>T | 5'UTR (SNP) | VAF 9/238 reads (4%) | called by muse, mutect2
- MALSU1 | chr7:23299108 A>T | 5'Flank (SNP) | VAF 45/82 reads (55%) | catalogued as rs912526663; called by muse, mutect2, varscan2
- MAP3K9 | c.*266C>G | 3'UTR (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- MAPK13 | c.-12C>T | 5'UTR (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- MCF2 | c.*258T>G | 3'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- MMP14 | c.108+306T>G | Intron (SNP) | VAF 53/98 reads (54%) | catalogued as rs1323491827; called by muse, varscan2
- MTAP | c.813+2643G>A | Intron (SNP) | VAF 35/400 reads (9%) | called by muse, mutect2
- NEXMIF | c.*679A>C | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- NLGN1 | c.*4048T>C | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NR6A1 | c.*180T>A | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- NXPH4 | c.*466C>T | 3'UTR (SNP) | VAF 135/298 reads (45%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*3724dup | 3'UTR (INS) | VAF 43/107 reads (40%) | called by mutect2, pindel, varscan2
- PLEKHH1 | c.3285-11C>G | Intron (SNP) | VAF 98/316 reads (31%) | called by muse, mutect2, varscan2
- PRECSIT | n.458dup | RNA (INS) | VAF 77/106 reads (73%) | catalogued as rs1178014204; called by mutect2, pindel, varscan2
- PROS1 | c.*941T>A | 3'UTR (SNP) | VAF 14/289 reads (5%) | called by muse, mutect2
- PWWP3A | chr19:1356333 G>A | 5'Flank (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- RNASEL | c.*123G>A | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- RSPH9 | c.*492C>T | 3'UTR (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- SERTAD2 | c.*2711G>T | 3'UTR (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- TCERG1 | c.2910+69T>C | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as rs1189389152; called by muse, mutect2, varscan2
- TGFA | c.*24C>T | 3'UTR (SNP) | VAF 66/130 reads (51%) | catalogued as rs782252830; called by muse, mutect2, varscan2
- TOMM34 | c.*836G>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TRAPPC2 | c.*95T>C | 3'UTR (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- VANGL1 | chr1:115696558 A>T | 3'Flank (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- ZNF764 | c.*1331A>G | 3'UTR (SNP) | VAF 41/92 reads (45%) | catalogued as rs901665425; called by muse, mutect2, varscan2
